Somatic mutation profile of tumor specimen MP2PRT-PATFGT-TMP1-A (aliquot MP2PRT-PATFGT-TMP1-A-1-0-D-A81Y-36) from MP2PRT case MP2PRT-PATFGT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.9 years (2,507 days).
Specimen MP2PRT-PATFGT-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9a4fa23b-e8b3-4e4e-88e3-56d2bc8ea659.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATFGT-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATFGT-NB1-A-1-0-D-A81Y-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6ff57254-6a12-4648-926f-c1d4d397020d

The open-access MAF lists 38 somatic variants for this specimen: 27 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 9, Nonsense Mutation 4, Frame Shift Ins 1, 5'Flank 1, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BBX | c.1921C>T p.R641* | Nonsense Mutation (SNP) | VAF 69/186 reads (37%) | catalogued as COSV57879776; called by muse, mutect2, varscan2
- BIRC7 | c.865G>A p.V289I (on ENST00000217169 / NM_139317.3; = p.V271I on NM_022161.4) | Missense Mutation (SNP) | VAF 261/585 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs748222291, COSV53901033; called by muse, mutect2, varscan2
- CNOT9 | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 97/564 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs768993950; called by muse, mutect2, varscan2
- EZH2 | c.2213_2214insACGG p.I739Rfs*20 (on ENST00000460911 / NM_001203247.2; = p.I744Rfs*20 on NM_004456.5) | Frame Shift Ins (INS) | VAF 125/386 reads (32%) | catalogued as COSV57450477; called by mutect2, pindel*, varscan2
- KRTAP10-1 | c.227C>T p.T76M | Missense Mutation (SNP) | VAF 427/1551 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.135); catalogued as rs782373435; called by muse, mutect2, varscan2
- MPL | c.1062C>G p.F354L | Missense Mutation (SNP) | VAF 238/552 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.471); catalogued as COSV65244008; called by muse, mutect2, varscan2
- PAX1 | c.1105G>A p.A369T | Missense Mutation (SNP) | VAF 112/600 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.325); catalogued as COSV68271704; called by muse, mutect2, varscan2
- POC1B | c.1297G>C p.E433Q | Missense Mutation (SNP) | VAF 136/365 reads (37%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.601); catalogued as COSV100543966, COSV57964303; called by muse, mutect2, varscan2
- RHBDF1 | c.682G>A p.V228I | Missense Mutation (SNP) | VAF 146/342 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs761973824, COSV51955233; called by muse, mutect2, varscan2
- SEMA3C | c.1121G>A p.R374H | Missense Mutation (SNP) | VAF 134/317 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs946026283, COSV54846826; called by muse, mutect2, varscan2
- STEAP1 | c.979G>A p.V327I | Missense Mutation (SNP) | VAF 121/297 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.104); catalogued as rs763487952, COSV99787692; called by muse, mutect2, varscan2
- THOC2 | c.443C>T p.S148L | Missense Mutation (SNP) | VAF 41/248 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV99832911; called by muse, mutect2, varscan2
- ANKRD20A1 | c.1693G>T p.E565* | Nonsense Mutation (SNP) | VAF 21/44 reads (48%) | called by mutect2, varscan2
- ATP7A | c.1375T>A p.S459T | Missense Mutation (SNP) | VAF 146/379 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CASTOR2 | c.935A>G p.E312G | Missense Mutation (SNP) | VAF 266/638 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- GABBR2 | c.739G>C p.D247H | Missense Mutation (SNP) | VAF 100/273 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GTPBP6 | c.1322G>A p.G441D | Missense Mutation (SNP) | VAF 340/686 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- IGHV4-59 | c.346_350delinsTAGGGGGCACAC p.R116* | Nonsense Mutation (INS) | VAF 120/318 reads (38%) | called by pindel, varscan2*
- KIAA1109 | c.15010G>C p.E5004Q | Missense Mutation (SNP) | VAF 91/201 reads (45%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- PHF11 | c.411G>C p.K137N | Missense Mutation (SNP) | VAF 141/369 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PLA2G15 | c.652A>G p.K218E | Missense Mutation (SNP) | VAF 200/455 reads (44%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- RB1 | c.1810G>C p.D604H | Missense Mutation (SNP) | VAF 109/298 reads (37%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RBP1 | c.161C>T p.T54M (on ENST00000619087 / NM_001365940.2; = p.T116M on NM_002899.5) | Missense Mutation (SNP) | VAF 100/490 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- SETD1B | c.4855C>T p.P1619S | Missense Mutation (SNP) | VAF 194/447 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- STEAP3 | c.456G>A p.W152* | Nonsense Mutation (SNP) | VAF 130/304 reads (43%) | called by muse, mutect2, varscan2
- USF3 | c.4360C>G p.H1454D | Missense Mutation (SNP) | VAF 162/394 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, varscan2
- VWA8 | c.1698G>A p.K566= | Splice Region (SNP) | VAF 12/214 reads (6%) | called by muse, mutect2
- ALPL | c.1353C>T p.H451= | Silent (SNP) | VAF 252/573 reads (44%) | catalogued as rs377110098; called by muse, mutect2, varscan2
- CCNI2 | c.582C>T p.C194= | Silent (SNP) | VAF 148/375 reads (39%) | catalogued as rs189626106, COSV66394322; called by muse, mutect2, varscan2
- DNAH1 | c.2103G>A p.E701= | Silent (SNP) | VAF 76/255 reads (30%) | called by muse, mutect2, varscan2
- PSD4 | c.2476C>T p.L826= | Silent (SNP) | VAF 78/461 reads (17%) | called by muse, mutect2, varscan2
- PTPRS | c.3261G>A p.T1087= | Silent (SNP) | VAF 113/738 reads (15%) | catalogued as rs781565996, COSV53621662; called by muse, mutect2, varscan2
- SLC25A18 | c.174G>A p.A58= | Silent (SNP) | VAF 212/490 reads (43%) | catalogued as rs1310075464, COSV100541212, COSV59409128; called by muse, mutect2, varscan2
- SLC35A2 | c.9G>A p.A3= | Silent (SNP) | VAF 230/555 reads (41%) | called by muse, mutect2, varscan2
- TRIM72 | c.885G>A p.P295= | Silent (SNP) | VAF 187/492 reads (38%) | catalogued as rs1463338666, COSV59066731, COSV59069005; called by muse, mutect2, varscan2
- VPS4A | c.192A>G p.L64= | Silent (SNP) | VAF 15/526 reads (3%) | called by muse, mutect2
- AL353804.6 | chrX:73829084 C>G | 3'Flank (SNP) | VAF 18/390 reads (5%) | called by muse, mutect2
- MFRP | chr11:119343883 C>T | 5'Flank (SNP) | VAF 165/396 reads (42%) | catalogued as rs563717527; called by muse, mutect2, varscan2
